Somatic mutation profile of tumor specimen TCGA-G2-A2EK-01A (aliquot TCGA-G2-A2EK-01A-22D-A18F-08) from TCGA case TCGA-G2-A2EK, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 57.5 years (20,995 days).
Specimen TCGA-G2-A2EK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e1f2145-c3e3-4a60-a56b-f7be69cd6a91.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G2-A2EK-10A (Blood Derived Normal), aliquot TCGA-G2-A2EK-10A-01D-A18F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49ad8ee6-6bc7-4795-a447-847be9dd3526

The open-access MAF lists 74 somatic variants for this specimen: 56 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 16, Nonsense Mutation 5, Frame Shift Ins 2, 5'UTR 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS18 | c.273G>C p.Q91H | Missense Mutation (SNP) | VAF 69/244 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV51418267, COSV99271018; called by muse, mutect2, varscan2
- ADGRF1 | c.2630C>T p.S877L | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1437747111, COSV51946320; called by muse, mutect2, varscan2
- ATG14 | c.1325G>A p.R442Q | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.242); catalogued as COSV55957097; called by muse, mutect2, varscan2
- BOD1L1 | c.6937G>A p.E2313K | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0.05); PolyPhen benign (0.257); catalogued as COSV50022780; called by muse, mutect2, varscan2
- C12orf45 | c.119T>A p.I40K | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as COSV55012905; called by muse, mutect2, varscan2
- CAMSAP3 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 72/250 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.707); catalogued as COSV50338927; called by muse, mutect2, varscan2
- CARD14 | c.1242C>G p.L414= | Splice Region (SNP) | VAF 20/83 reads (24%) | catalogued as COSV60124699; called by muse, mutect2, varscan2
- CD164 | c.398C>G p.S133C | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as COSV51533914, COSV51534058; called by muse, mutect2
- CD19 | c.1153G>A p.V385I | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as rs1378572982, COSV61188949; called by muse, mutect2, varscan2
- CDKN2B | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); catalogued as rs1167893458, COSV52805455; called by muse, mutect2, varscan2
- CTNNA2 | c.1297A>G p.N433D | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.745); catalogued as COSV58161205; called by mutect2, varscan2
- CX3CL1 | c.878C>T p.S293L | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV50056209; called by muse, mutect2, varscan2
- CYP4Z1 | c.1415G>T p.R472L | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV61965626, COSV61966444; called by muse, mutect2, varscan2
- CYTH4 | c.613C>T p.R205W | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as rs766349067, COSV50633612; called by muse, mutect2, varscan2
- DENND4A | c.2893G>A p.V965I | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs748829507, COSV71265181; called by muse, mutect2, varscan2
- DNTT | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 63/156 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as COSV64523251; called by muse, mutect2, varscan2
- HERC2 | c.5509C>G p.Q1837E | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55332252; called by muse, mutect2, varscan2
- KCNA6 | c.94G>A p.G32S | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.83); PolyPhen benign (0.006); catalogued as rs767444726, COSV54976243; called by muse, mutect2, varscan2
- KDM6A | c.439C>T p.Q147* | Nonsense Mutation (SNP) | VAF 11/16 reads (69%) | catalogued as COSV100937839; called by muse, mutect2, varscan2
- KLHL7 | c.355G>A p.D119N (on ENST00000339077 / NM_001031710.3; = p.D71N on NM_018846.5) | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV59162410; called by muse, mutect2
- KNL1 | c.2494G>C p.E832Q (on ENST00000346991 / NM_170589.5; = p.E806Q on NM_144508.5) | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.55); catalogued as COSV61150570; called by muse, mutect2, varscan2
- LARGE1 | c.948G>C p.W316C | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV61665109; called by muse, mutect2, varscan2
- LYST | c.4622C>T p.S1541L | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67709249; called by muse, mutect2, varscan2
- MIPOL1 | c.950C>T p.S317F | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV59384669; called by muse, mutect2
- MPND | c.1211C>G p.P404R | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as rs764125142, COSV53658228; called by muse, mutect2, varscan2
- NAPEPLD | c.842dup p.A282Rfs*11 | Frame Shift Ins (INS) | VAF 15/63 reads (24%) | catalogued as rs746683932; called by mutect2, varscan2
- NBEA | c.6308C>T p.T2103M | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.677); catalogued as rs756245795, COSV59777018; called by muse, mutect2, varscan2
- NOXO1 | c.793C>A p.R265S (on ENST00000397280 / NM_172168.3; = p.R259S on NM_144603.4) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as COSV50191637; called by muse, mutect2, varscan2
- NPFFR1 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV53333718; called by muse, mutect2, varscan2
- OR2T33 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 73/284 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.187); catalogued as rs777287203, COSV100531481, COSV58816166; called by muse, mutect2, varscan2
- PCDH18 | c.2181G>C p.E727D | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.978); catalogued as COSV61269681; called by muse, mutect2, varscan2
- PCDHA9 | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.615); catalogued as rs1554143464, COSV65328545; called by muse, mutect2, varscan2
- PCDHB15 | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.901); catalogued as rs1246396253, COSV51068929; called by muse, mutect2, varscan2
- PCDHB4 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV52019947; called by muse, varscan2
- PLSCR1 | c.34C>A p.H12N | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.017); catalogued as COSV61013134; called by muse, mutect2, varscan2
- PLXNB2 | c.4221C>G p.I1407M | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV63782783; called by mutect2, varscan2
- POLR1A | c.4324G>A p.D1442N | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs765131837, COSV55695279; called by muse, varscan2
- PTPN3 | c.2356C>T p.R786* | Nonsense Mutation (SNP) | VAF 47/121 reads (39%) | catalogued as rs770792229, COSV52705632, COSV52709603; called by muse, mutect2, varscan2
- QSER1 | c.4861G>A p.D1621N (on ENST00000399302; = p.D1750N on NM_001076786.3) | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.677); catalogued as COSV67901081; called by muse, mutect2, varscan2
- RGS5 | c.470G>C p.R157T | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.395); catalogued as COSV100008902, COSV58352409; called by muse, mutect2, varscan2
- RHOA | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.965); catalogued as COSV69041753, COSV69042135; called by muse, mutect2, varscan2
- RPP38 | c.41G>A p.R14H | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs752169129, COSV65382153; called by muse, mutect2, varscan2
- SLC66A1 | c.653C>G p.S218C | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.886); catalogued as COSV64320832, COSV64321083; called by muse, mutect2, varscan2
- SLC6A19 | c.861C>G p.I287M | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58672392, COSV58674973; called by muse, mutect2, varscan2
- SNX27 | c.1180A>G p.K394E | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.147); catalogued as COSV64326849; called by muse, mutect2, varscan2
- SORCS1 | c.2681A>G p.H894R | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as rs1248990817, COSV53879717; called by muse, mutect2, varscan2
- TYMP | c.23G>A p.G8E | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.01); catalogued as rs1284840530, COSV52689709, COSV99329590; called by muse, mutect2
- TYR | c.263C>T p.T88I | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54479581; called by muse, mutect2, varscan2
- UBTF | c.1801G>A p.G601S | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.27); PolyPhen probably damaging (1); catalogued as COSV57187082; called by muse, mutect2, varscan2
- VARS1 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1288920757, COSV65151983; called by muse, mutect2, varscan2
- ARID1A | c.3951dup p.M1318Dfs*5 | Frame Shift Ins (INS) | VAF 22/108 reads (20%) | called by pindel, varscan2
- BOD1L1 | c.7378G>T p.E2460* | Nonsense Mutation (SNP) | VAF 20/81 reads (25%) | called by muse, mutect2, varscan2
- CHPF | c.449T>G p.F150C | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- HDAC1 | c.1090C>T p.Q364* | Nonsense Mutation (SNP) | VAF 29/124 reads (23%) | called by muse, mutect2, varscan2
- LSM14B | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.019); called by muse, mutect2
- POLR1A | c.4288G>T p.E1430* | Nonsense Mutation (SNP) | VAF 18/76 reads (24%) | called by muse, varscan2
- ADPRH | c.513G>A p.G171= | Silent (SNP) | VAF 38/162 reads (23%) | catalogued as rs777008951, COSV63695318; called by muse, mutect2, varscan2
- CACNA1B | c.960C>G p.L320= | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as COSV53134049; called by muse, mutect2, varscan2
- CDH26 | c.156C>T p.S52= | Silent (SNP) | VAF 28/158 reads (18%) | catalogued as COSV54849343; called by muse, mutect2, varscan2
- CHPF | c.450C>T p.F150= | Silent (SNP) | VAF 3/9 reads (33%) | called by muse, mutect2
- ELF2 | c.372T>G p.P124= (on ENST00000379550 / NM_001331036.2; = p.P64= on NM_006874.4) | Silent (SNP) | VAF 27/87 reads (31%) | catalogued as COSV55494208; called by muse, mutect2, varscan2
- FGD5 | c.1929G>A p.P643= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as rs775722294, COSV53242582; called by muse, mutect2, varscan2
- H2AC14 | c.150G>A p.V50= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs1329192378, COSV100297447; called by muse, mutect2, varscan2
- HMCN1 | c.6879C>T p.T2293= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as COSV54913985; called by muse, mutect2, varscan2
- INPP5A | c.738C>G p.L246= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as COSV61250230; called by muse, mutect2, varscan2
- PCDHA4 | c.2202G>A p.P734= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as rs781832159, COSV63538794; called by muse, mutect2, varscan2
- POLR1A | c.4440G>C p.L1480= | Silent (SNP) | VAF 42/167 reads (25%) | catalogued as COSV55690019, COSV55695266; called by muse, mutect2, varscan2
- SEMA3D | c.75A>G p.L25= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as rs1357746669, COSV52397426; called by muse, mutect2, varscan2
- SLFN13 | c.1428C>G p.L476= | Silent (SNP) | VAF 16/123 reads (13%) | catalogued as COSV53193236; called by muse, mutect2, varscan2
- SP1 | c.711C>G p.P237= (on ENST00000327443 / NM_138473.3; = p.P230= on NM_003109.1) | Silent (SNP) | VAF 24/87 reads (28%) | catalogued as COSV59403919; called by muse, mutect2, varscan2
- SPTB | c.2526G>A p.Q842= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as COSV67633066; called by muse, mutect2, varscan2
- TNFAIP3 | c.840G>A p.R280= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as COSV52800047; called by muse, mutect2, varscan2
- CAMLG | c.-1G>T | 5'UTR (SNP) | VAF 9/27 reads (33%) | catalogued as COSV99777679; called by muse, mutect2
- HERC2P3 | n.1198C>T | RNA (SNP) | VAF 5/45 reads (11%) | catalogued as rs1401646158; called by muse, mutect2, varscan2
